Gene-level copy-number profile of tumor specimen TCGA-EE-A2MM-06A from TCGA case TCGA-EE-A2MM, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 72.6 years (26,535 days).
Specimen TCGA-EE-A2MM-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.53d6c0d9-2ecc-4fa2-b61b-d4c3f03ed796.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A2MM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7376f7a2-f5ee-4685-bcf4-0a9796b7b9f4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 1; copy number 2: 8,955; copy number 3: 12,562; copy number 4: 31,486; copy number 5: 2,956; copy number 6: 792; copy number 7: 1,474; copy number 9: 117; copy number 10: 3; copy number 11: 1,410; copy number 12: 26; copy number 21: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A2MM-06A-11D-A194-01): tumor purity 0.9, ploidy 3.83, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:150,078,445–151,015,727, 7 genes (within-gene range 0–2): DCLK2, RNU7-194P, LRBA, AC092612.1, AC110813.1, MAB21L2, ZBTB8OSP1.
- chr4:151,949,338–152,318,364, 11 genes: AC097375.4, AC097375.3, RNA5SP169, AC097375.5, LINC02273, AC079340.3, AC079340.1, AC079340.2, RN7SL446P, AC080078.1, AC080078.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,573 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:167,607–58,438,364, 1,527 genes, copy number 9–11 (broad region; genes not listed).
- chr11:93,991,346–95,757,442, 43 genes, copy number 12–21: AP002795.1, HPRT1P3, HEPHL1, PHBP16, PANX1, AP002784.1, ARPC3P3, IZUMO1R, GPR83, MRE11, MIR548L, AP000786.1, ANKRD49, C11orf97, FUT4, PIWIL4, AP000943.2, AP000943.3, AP000943.1, LINC02700, AMOTL1, AP002383.2, ST13P11, CWC15, KDM4D, AP002383.1, KDM4E, AP002383.5, AP002383.3, AP002383.4, KDM4F, AP001264.1, SRSF8, ENDOD1, BUD13P1, AP000787.2, AP000787.1, SESN3, AP000787.3, AP001790.1, AP000820.2, AP000820.1, AP001877.1.
- chr12:23,529,504–24,562,544, 1 gene, copy number 10 (within-gene range 4–10): SOX5.
- chr12:24,212,421–24,260,056, 2 genes, copy number 10: MIR920, SOX5-AS1.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
